HCMI case HCM-CSHL-1268-C24 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Other and unspecified parts of biliary tract. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/94eb0a19-ba87-4ca8-a021-01a2609845b3

Demographics
Sex at birth: male; Year of birth: 1961; Vital status: Alive.

Diagnoses (2)
1. Adenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8140/3; ICD-10 code: C24.1; Tissue or organ of origin: Ampulla of Vater; Classification of tumor: primary; Age at diagnosis: 58.9 years (21,495 days); AJCC staging edition: 8th; AJCC pathologic T: T2; AJCC pathologic N: N2; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIIB; Tumor grade: G3; Metastasis at diagnosis: No Metastasis; Prior malignancy: no; Prior treatment: No; Residual disease: R0; Tumor confined to organ of origin: No.
   Pathology details: Lymph nodes positive: 11; Lymph nodes tested: 46; Lymphatic invasion present: No; Perineural invasion present: No; Vascular invasion present: No.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis; Days to treatment start: -8 days.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Fluorouracil + Irinotecan Hydrochloride + Leucovorin Calcium + Oxaliplatin; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Regimen or line of therapy: FOLFIRINOX; Days to treatment start: 51 days; Days to treatment end: 202 days.
   Recorded as not given: neoadjuvant treatment (type not reported); adjuvant Hormone Therapy, for residual disease; adjuvant Immunotherapy (Including Vaccines), for residual disease; adjuvant Radiation Therapy, NOS, for residual disease; adjuvant Targeted Molecular Therapy, for residual disease.
2. Adenocarcinoma, metastatic, NOS: ICD-O-3 morphology code: 8140/6; ICD-10 code: C77.2; Tissue or organ of origin: Ampulla of Vater; Site of resection or biopsy: Lymph node, NOS; Classification of tumor: metastasis; Age at diagnosis: 58.9 years (21,503 days); Days to diagnosis: 8 days; Residual disease: R0; Tumor confined to organ of origin: No.
   Pathology details: Lymph nodes positive: 11; Lymph nodes tested: 46; Lymphatic invasion present: Yes; Perineural invasion present: No; Vascular invasion present: No.

Follow-up (2 entries)
- Days to follow up: 434 days (1.2 years); Disease response: Stable Disease; Progression or recurrence: No.
- Follow-up contact recording only the day: day 315.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 73 kg; Height: 165 cm; BMI: 27.

Exposures
- Tobacco smoking status: Current Reformed Smoker for > 15 yrs.

Family history
- Relative with cancer history: no.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample HCM-CSHL-1268-C24-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: Frozen.
  Slide HCM-CSHL-1268-C24-06A-01-S1-HE: Section location: Top; Percent tumor cells: 60; Percent tumor nuclei: 69; Percent normal cells: 27; Percent necrosis: 5; Percent stromal cells: 8; Percent lymphocyte infiltration: 1; Percent monocyte infiltration: 13; Percent neutrophil infiltration: 9.
  Slide HCM-CSHL-1268-C24-06A-01-S2-HE: Section location: Bottom; Percent tumor cells: 55; Percent tumor nuclei: 71; Percent normal cells: 22; Percent necrosis: 7; Percent stromal cells: 16; Percent lymphocyte infiltration: 9; Percent monocyte infiltration: 3; Percent neutrophil infiltration: 4.
- Sample HCM-CSHL-1268-C24-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Preservation method: Frozen.
  Slide HCM-CSHL-1268-C24-11A-01-S1-HE: Section location: Top; Percent tumor cells: 0; Percent tumor nuclei: 0; Percent normal cells: 100; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
  Slide HCM-CSHL-1268-C24-11A-01-S2-HE: Section location: Bottom; Percent tumor cells: 0; Percent tumor nuclei: 0; Percent normal cells: 100; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample HCM-CSHL-1268-C24-85M: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen.
